Somatic mutation profile of tumor specimen TCGA-49-AARN-01A (aliquot TCGA-49-AARN-01A-21D-A410-08) from TCGA case TCGA-49-AARN, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.4 years (20,605 days).
Specimen TCGA-49-AARN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ece21e7-6197-41b3-8152-cc388dfe2ed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AARN-11A (Solid Tissue Normal), aliquot TCGA-49-AARN-11A-11D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c353ee74-c8e3-4984-974c-0cf3b8e59c3c

The open-access MAF lists 811 somatic variants for this specimen: 639 protein-altering or splice-affecting, 147 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 565, Silent 147, Nonsense Mutation 32, Splice Site 14, Frame Shift Del 12, Intron 11, RNA 9, Splice Region 7, Frame Shift Ins 4, 3'Flank 3, Translation Start Site 2, In Frame Del 2.

Variants (750 of 811; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as rs886043247, CM030506, COSV57295964, COSV99927064; ClinVar: pathogenic; called by muse, mutect2
- SETD2 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57429702; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4729T>G p.L1577V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV101330081; called by muse, mutect2, varscan2
- ABCD3 | c.781T>A p.Y261N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100238966; called by muse, mutect2, varscan2
- ABCG4 | c.671T>C p.F224S | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100266821; called by muse, mutect2, varscan2
- ABHD6 | c.755G>T p.S252I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs1343082928, COSV99917049; called by muse, mutect2
- AC090517.4 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99974621; called by muse, mutect2
- AC093827.5 | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99892935; called by muse, mutect2
- AC126283.2 | c.1173A>C p.Q391H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as COSV101144506; called by muse, mutect2
- ACE | c.1438A>G p.S480G | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as COSV99327212; called by muse, mutect2
- ACTN2 | c.1832G>A p.W611* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100856852; called by muse, mutect2, varscan2
- ACTR2 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99573946; called by muse, mutect2
- ACY3 | c.433-1G>T p.X145_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99663035; called by muse, mutect2
- ADAM21 | c.575A>C p.N192T | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV99961093; called by muse, mutect2
- AFF2 | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100650288; called by muse, mutect2, varscan2
- AGAP1 | c.2321A>T p.H774L (on ENST00000304032 / NM_001037131.3; = p.H721L on NM_014914.5) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100365565; called by muse, mutect2, varscan2
- AGRP | c.250T>G p.S84A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99341194; called by muse, mutect2
- AGTR2 | c.396T>G p.I132M | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100903586; called by muse, mutect2
- AHNAK2 | c.14144A>C p.K4715T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV100317820; called by muse, mutect2
- AHNAK2 | c.8467T>G p.F2823V | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100317822; called by muse, mutect2
- AHRR | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1339270933, COSV100327464; called by muse, varscan2
- AK5 | c.454A>G p.I152V (on ENST00000354567 / NM_174858.3; = p.I126V on NM_012093.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100481502; called by muse, mutect2
- ALDH3A1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV99855908; called by muse, mutect2, varscan2
- AMOT | c.1898G>A p.R633K (on ENST00000371959 / NM_001113490.1; = p.R224K on NM_133265.3) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100495174; called by muse, mutect2
- AMOT | c.1681G>T p.A561S (on ENST00000371959 / NM_001113490.1; = p.A152S on NM_133265.3) | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100495178; called by muse, mutect2, varscan2
- AMPH | c.2051G>C p.G684A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780237235, COSV100342439; called by muse, mutect2, varscan2
- ANAPC2 | c.521A>T p.Q174L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100119114; called by muse, mutect2, varscan2
- ANK1 | c.5387T>G p.V1796G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.021); catalogued as COSV99225573; called by muse, mutect2, varscan2
- ANK2 | c.4816A>T p.K1606* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100002084; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV99783615; called by muse, mutect2
- ANOS1 | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as COSV99390978; called by muse, mutect2, varscan2
- APC | c.6026C>T p.P2009L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758141039, COSV99968226; called by muse, mutect2
- ARHGAP31 | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99957231; called by muse, mutect2
- ARHGEF7 | c.2239G>T p.D747Y (on ENST00000375741 / NM_001113511.2; = p.D726Y on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1190343654, COSV99521662; called by muse, mutect2, varscan2
- ARID1A | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 6/152 reads (4%) | catalogued as COSV61371604, COSV61372723; called by muse, mutect2
- ARL1 | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.514); catalogued as COSV99880348; called by muse, mutect2
- ARMC6 | c.1292A>T p.Q431L (on ENST00000392336; = p.Q406L on NM_033415.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99523063; called by muse, mutect2
- ARMCX2 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100168191; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as COSV100771924; called by muse, mutect2, varscan2
- ASAP1 | c.3183A>C p.K1061N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100727370; called by muse, mutect2
- ASB12 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100744734; called by muse, mutect2, varscan2
- ASH1L | c.1180A>C p.S394R | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV100853465; called by muse, mutect2
- ASPM | c.6403A>G p.S2135G | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV99660543; called by muse, mutect2
- ASTN1 | c.3544G>C p.D1182H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100707098; called by muse, mutect2, varscan2
- ASXL3 | c.4175G>T p.R1392I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV99325216; called by muse, mutect2, varscan2
- ATP1A3 | c.56A>G p.D19G (on ENST00000545399 / NM_001256214.2; = p.D6G on NM_152296.5) | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100132305; called by muse, mutect2
- ATP6AP1 | c.1171T>A p.S391T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.16); catalogued as COSV100870696; called by muse, mutect2, varscan2
- ATP6V1E1 | c.339A>C p.Q113H | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99494318; called by muse, mutect2
- ATP7A | c.4449C>A p.D1483E | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100430998; called by muse, mutect2, varscan2
- ATP8B2 | c.3022del p.V1008Cfs*94 (on ENST00000672630; = p.V975Cfs*94 on NM_001367934.1 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV100528285; called by mutect2, varscan2
- ATRX | c.3044G>A p.G1015D | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV100970905; called by muse, mutect2, varscan2
- ATRX | c.2417A>C p.K806T | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100970906; called by muse, mutect2
- ATXN3L | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 10/254 reads (4%) | catalogued as COSV101019419, COSV66075487; called by muse, mutect2
- ATXN7L2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs1247855589, COSV100149870; called by muse, mutect2
- AURKAIP1 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366506763, COSV100408695; called by muse, mutect2, varscan2
- AVPR1A | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100146862, COSV54546119; called by muse, mutect2
- B4GALNT3 | c.1395A>C p.Q465H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV99843133; called by muse, mutect2
- BCAS1 | c.1666T>G p.F556V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101006257; called by muse, mutect2
- BCOR | c.3071C>A p.S1024* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100653437, COSV60700385; called by muse, mutect2
- BIRC3 | c.1689A>T p.K563N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99679999; called by muse, mutect2
- BMPR1B | c.1109C>A p.T370N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.939); catalogued as COSV99215953; called by muse, mutect2, varscan2
- BNC2 | c.1469G>T p.S490I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101033488; called by muse, mutect2, varscan2
- BSN | c.5690A>C p.Q1897P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99608757; called by muse, mutect2
- BTD | c.180A>T p.Q60H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100329628; called by muse, mutect2, varscan2
- C11orf87 | c.360G>C p.R120S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs552501040, COSV100535823; called by muse, mutect2, varscan2
- C2orf78 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV101280988; called by muse, mutect2, varscan2
- C5AR2 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1235987068, COSV99953785; called by muse, mutect2
- C8orf76 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1216621333, COSV99415071; called by muse, varscan2
- CA5B | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100590744; called by muse, mutect2, varscan2
- CACNA1C | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100219482; called by muse, mutect2, varscan2
- CACNA1G | c.3845T>C p.V1282A | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100661946; called by muse, mutect2
- CACNA1S | c.5153G>T p.C1718F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100755083; called by muse, mutect2, varscan2
- CAGE1 | c.1473C>A p.F491L (on ENST00000512086; = p.F355L on NM_205864.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV99699776; called by muse, mutect2
- CCDC149 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.856); catalogued as COSV100164732; called by muse, mutect2
- CCND2 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as COSV99714281; called by muse, mutect2, varscan2
- CCR3 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62461413, COSV62461552; called by muse, mutect2, varscan2
- CDADC1 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV99212568; called by muse, mutect2, varscan2
- CDC25C | c.1255T>C p.F419L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100086750; called by muse, mutect2
- CDCP2 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100313526; called by muse, mutect2, varscan2
- CDH15 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs765075305; called by muse, mutect2
- CDK12 | c.2557A>C p.K853Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV101420480; called by muse, mutect2
- CDON | c.3506G>T p.G1169V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99701501; called by muse, mutect2, varscan2
- CDX4 | c.471T>A p.Y157* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs759350426, COSV100999137; called by muse, mutect2, varscan2
- CENPF | c.218T>C p.M73T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV100871727; called by muse, mutect2
- CEP170 | c.4713C>G p.F1571L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); catalogued as rs1429048521, COSV100317246; called by muse, mutect2, varscan2
- CHD2 | c.1300G>T p.G434* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100560732; called by muse, mutect2, varscan2
- CHD6 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV100498361; called by muse, mutect2, varscan2
- CHL1 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.011); catalogued as COSV99851453; called by muse, mutect2
- CHRNA6 | c.124T>G p.F42V | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99373267; called by muse, mutect2
- CHST1 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs976283351, COSV57323126; called by muse, mutect2, varscan2
- CLCN4 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101073869; called by muse, mutect2
- CLECL1 | c.5T>G p.V2G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100590103; called by muse, mutect2
- CLECL1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100590105; called by muse, mutect2
- CLIP2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99791699; called by muse, mutect2
- CLSTN2 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV71725496; called by muse, mutect2, varscan2
- CMTM5 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59306648; called by muse, mutect2
- CNTNAP4 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.102); catalogued as COSV100271827; called by muse, mutect2
- CNTNAP5 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV70502006; called by muse, mutect2
- CNTNAP5 | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101443672; called by muse, mutect2, varscan2
- CNTNAP5 | c.3894C>A p.S1298R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs201132721, COSV101443673, COSV70481109; called by muse, mutect2, varscan2
- COL10A1 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as COSV99684281; called by muse, mutect2, varscan2
- COL11A1 | c.1495T>A p.Y499N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as COSV100616963; called by mutect2, varscan2
- COL19A1 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506494; called by muse, mutect2, varscan2
- COL5A2 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66407002; called by muse, mutect2, varscan2
- COL7A1 | c.5387A>C p.N1796T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV100096539; called by muse, mutect2
- COL9A3 | c.1773C>A p.D591E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.936); catalogued as rs770282996, COSV100102226; called by muse, mutect2, varscan2
- COPA | c.1831-1G>A p.X611_splice | Splice Site (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99615894; called by muse, mutect2, varscan2
- COPS3 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99253705; called by muse, mutect2
- COPS4 | c.1140A>T p.Q380H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100018590; called by muse, mutect2
- CP | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as COSV99224185; called by muse, mutect2, varscan2
- CPB1 | c.1120T>G p.S374A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as COSV99294363; called by muse, mutect2
- CPQ | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.122); catalogued as COSV99612706; called by muse, mutect2, varscan2
- CPSF7 | c.1338T>G p.D446E (on ENST00000394888 / NM_001136040.4; = p.D489E on NM_024811.4) | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100467387; called by muse, mutect2
- CREG1 | c.388G>C p.A130P | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100981904; called by muse, mutect2, varscan2
- CRLF2 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.25); catalogued as COSV101053726; called by muse, mutect2, varscan2
- CRYZ | c.195A>T p.L65F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100558628; called by muse, mutect2, varscan2
- CTNNAL1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100336602; called by muse, mutect2, varscan2
- CTRC | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101036377, COSV65621439; called by muse, mutect2
- CTSW | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV100327403; called by muse, mutect2
- CTTNBP2 | c.3572A>C p.K1191T | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.816); catalogued as COSV99354164; called by muse, mutect2
- CYBB | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1556469833, COSV101059770; called by muse, mutect2, varscan2
- CYP2A13 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV57837253; called by muse, mutect2, varscan2
- CYP46A1 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV99952673; called by muse, mutect2
- DDX19B | c.234A>T p.E78D | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV99850005; called by muse, mutect2
- DDX4 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100737579; called by muse, mutect2, varscan2
- DENND4B | c.4198G>T p.V1400F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1182708184, COSV100768734; called by muse, mutect2, varscan2
- DEPDC4 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV100147360; called by muse, mutect2, varscan2
- DGKG | c.2344T>C p.S782P | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.497); catalogued as COSV99403544; called by muse, mutect2
- DHX34 | c.867T>G p.D289E | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169649; called by muse, mutect2
- DIS3L2 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99806482; called by muse, mutect2, varscan2
- DISP3 | c.3499T>C p.C1167R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763803188, COSV99608931; called by muse, mutect2, varscan2
- DLGAP2 | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101422089; called by muse, mutect2, varscan2
- DMD | c.8467C>A p.L2823M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.177); catalogued as COSV100627680; called by muse, mutect2, varscan2
- DMD | c.7755G>T p.W2585C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD159993, CM066783, COSV100627685, COSV58912282; called by mutect2, varscan2
- DMD | c.6568C>A p.L2190M | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as rs1297126285, COSV100626558, COSV100627689; called by muse, mutect2, varscan2
- DNAH1 | c.2993A>G p.N998S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs1238214853, COSV101326107; called by mutect2, varscan2
- DNAH10 | c.3938C>A p.P1313Q (on ENST00000409039; = p.P1252Q on NM_207437.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV101292323; called by muse, mutect2, varscan2
- DNAH14 | c.895G>A p.D299N (on ENST00000445597; = p.D172N on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100835900, COSV64780695; called by muse, varscan2
- DNAH3 | c.1955T>G p.I652S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99768030; called by muse, mutect2
- DNAJC13 | c.3368G>C p.G1123A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99607426; called by muse, mutect2, varscan2
- DNER | c.771T>A p.S257R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100519255; called by muse, mutect2, varscan2
- DOCK2 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99913049; called by muse, mutect2
- DOCK3 | c.4178A>C p.E1393A | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV99812752; called by muse, mutect2
- DOCK8 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs780612775, COSV101210287; called by muse, mutect2, varscan2
- DPH7 | c.597G>C p.W199C | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99483577; called by muse, mutect2
- DPPA4 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1303329378, COSV59511936; called by muse, mutect2
- DPPA4 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100169482; called by muse, mutect2
- DPY19L2 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116816; called by mutect2, varscan2
- DRC7 | c.695A>G p.K232R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1403239570, COSV100395667; called by muse, mutect2
- DSEL | c.2593G>A p.V865I | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs781291532, COSV100025727; called by muse, mutect2
- DSG4 | c.2774T>A p.F925Y | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV100355982; called by muse, mutect2
- DSTYK | c.2750A>C p.N917T | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV100904601; called by muse, mutect2, varscan2
- DYNC1H1 | c.10107A>C p.K3369N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV100795015; called by muse, mutect2
- DYNC1LI1 | c.1285A>C p.K429Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV99818193; called by muse, mutect2, varscan2
- DZANK1 | c.1310G>T p.G437V (on ENST00000262547 / NM_001099407.1; = p.G244V on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99362599; called by muse, mutect2, varscan2
- EFNA1 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100310316, COSV100310381; called by muse, mutect2
- ELOA | c.1504-1G>T p.X502_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV69309989; called by muse, mutect2
- EML2 | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99840103; called by muse, mutect2
- EPHA5 | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899407; called by muse, mutect2, varscan2
- EPHB1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV67654980, COSV67659512, COSV67664485; called by muse, mutect2
- ERAL1 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV99650372; called by muse, mutect2, varscan2
- ESPL1 | c.2846T>G p.I949S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99229414; called by muse, mutect2, varscan2
- EXOC6B | c.2381T>G p.L794R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99724681; called by muse, mutect2, varscan2
- EXOC6B | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1472004973, COSV99724683; called by muse, mutect2, varscan2
- FAF2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99990222, COSV99990513; called by muse, mutect2
- FAM114A2 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.134); catalogued as rs776906272, COSV100697725; called by muse, mutect2, varscan2
- FAM160A2 | c.364G>T p.G122W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV99792141; called by muse, mutect2, varscan2
- FAM3D | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV62558761; called by muse, mutect2, varscan2
- FAM47C | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV100792674; called by muse, mutect2, varscan2
- FAT3 | c.2192C>A p.S731Y | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as COSV99966974; called by muse, mutect2
- FAT3 | c.10915C>T p.Q3639* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99966975; called by muse, mutect2, varscan2
- FBN2 | c.3583C>A p.R1195S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV99328207; called by mutect2, varscan2
- FBN3 | c.2732-1G>T p.X911_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV54457572, COSV99561116; called by muse, mutect2, varscan2
- FBXO39 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100386217; called by muse, mutect2, varscan2
- FCRL1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV63824930; called by muse, mutect2
- FERD3L | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372652635; called by muse, mutect2, varscan2
- FLG | c.1212A>C p.Q404H | Missense Mutation (SNP) | VAF 40/426 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100911650; called by muse, mutect2
- FLRT3 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99434730; called by muse, mutect2, varscan2
- FMNL1 | c.2717A>T p.K906M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100056582; called by muse, mutect2
- FNBP1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV100852725; called by muse, mutect2
- FOXG1 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1309285440, COSV100486878, COSV57396187; called by muse, mutect2, varscan2
- FRAS1 | c.4243A>G p.N1415D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99352884; called by muse, mutect2, varscan2
- FREM1 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.164); catalogued as rs1445818142, COSV101084777; called by muse, mutect2
- FRMD1 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1285399910, COSV99349837; called by muse, mutect2, varscan2
- FRS2 | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100166110; called by muse, mutect2, varscan2
- FSCN3 | c.1410del p.N471Mfs*71 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV56170013; called by mutect2, pindel
- FSHR | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.761); catalogued as COSV100437347; called by muse, mutect2
- GABRG1 | c.248T>G p.I83R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99778204; called by mutect2, varscan2
- GARS1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs1270150388, COSV101220147; called by muse, mutect2, varscan2
- GDAP1 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.041); catalogued as COSV99619645; called by muse, mutect2, varscan2
- GHR | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100051011; called by muse, mutect2, varscan2
- GLS | c.1810T>G p.F604V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100290185; called by muse, mutect2
- GNB3 | c.448C>A p.R150S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.945); catalogued as COSV99301324; called by muse, mutect2, varscan2
- GNE | c.202G>A p.E68K (on ENST00000396594 / NM_001128227.3; = p.E37K on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100929991; called by muse, mutect2
- GOLGA5 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as COSV99370995; called by muse, mutect2, varscan2
- GOLGB1 | c.2069A>T p.K690I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100511052; called by muse, mutect2
- GOPC | c.1052A>C p.E351A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99271036; called by muse, mutect2
- GPC5 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100994380, COSV65617949; called by muse, mutect2, varscan2
- GPN3 | c.264T>G p.F88L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99959854; called by muse, mutect2, varscan2
- GPR101 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981469; called by muse, mutect2, varscan2
- GPR6 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99254383; called by muse, mutect2
- GPR65 | c.622C>A p.Q208K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV50862393, COSV99966087; called by muse, mutect2, varscan2
- GPRASP1 | c.3026G>T p.G1009V | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV100851011; called by muse, mutect2, varscan2
- GPRASP1 | c.3973C>A p.L1325I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100851012; called by muse, mutect2, varscan2
- GPRASP2 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100176785; called by muse, mutect2, varscan2
- GRIN2A | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866473134, COSV58018267; called by muse, mutect2, varscan2
- GRM8 | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867364484, COSV58817047, COSV58838935; called by muse, mutect2, varscan2
- GRM8 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100283569; called by muse, mutect2, varscan2
- GSTM5 | c.119A>C p.D40A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99859624; called by muse, mutect2
- GUSB | c.1387T>G p.L463V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV100512651; called by mutect2, varscan2
- H2BC3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV63551149; called by muse, mutect2, varscan2
- H3C11 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.321); catalogued as COSV100137944; called by muse, mutect2, varscan2
- H3C4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV61911648, COSV61911890; called by muse, mutect2
- HADHB | c.1018T>G p.F340V | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100502037; called by muse, mutect2
- HAS1 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99708436; called by muse, mutect2
- HAS2 | c.279A>C p.Q93H | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100391883, COSV100392175; called by muse, mutect2, varscan2
- HDAC10 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99352391; called by muse, mutect2
- HDAC6 | c.1324A>C p.T442P | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100490930; called by muse, mutect2
- HDX | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99947433; called by muse, varscan2
- HECW1 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs779442609, COSV67822270, COSV67840029; called by mutect2, varscan2
- HECW1 | c.3343T>A p.Y1115N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101223816; called by muse, mutect2
- HERC1 | c.11805A>C p.K3935N | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV101496621; called by muse, mutect2
- HIPK2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100702291; called by muse, mutect2
- HOXB6 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.083); catalogued as COSV99494572; called by muse, mutect2, varscan2
- HSPA12A | c.1372A>T p.S458C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100979841, COSV65021891; called by muse, mutect2
- HTATSF1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1231666802, COSV54478956; called by muse, mutect2
- HUWE1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV99472737; called by muse, mutect2
- HYDIN | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217015474, COSV99863538; called by muse, mutect2, varscan2
- IARS2 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100228379; called by muse, mutect2, varscan2
- IGFBP5 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV99288964; called by muse, mutect2
- IGHG3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs759037989; called by muse, mutect2
- IL18RAP | c.1684A>T p.K562* | Nonsense Mutation (SNP) | VAF 7/153 reads (5%) | catalogued as COSV99962098; called by muse, mutect2
- IL1RL1 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.109); catalogued as rs753297060, COSV99294181; called by muse, mutect2, varscan2
- IL31RA | c.1919T>C p.L640S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100732715; called by muse, mutect2, varscan2
- ING3 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100253331, COSV59951940; called by muse, mutect2
- INTS14 | c.1108G>A p.G370S (on ENST00000313182 / NM_001366360.2; = p.G291S on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV57528119; called by muse, mutect2, varscan2
- ITPR2 | c.6460C>T p.H2154Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101190025; called by muse, mutect2, varscan2
- IWS1 | c.1658T>G p.I553S | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99767322; called by muse, mutect2
- JAK3 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1207720672, COSV101512963, COSV71687214; called by muse, mutect2, varscan2
- KCNH3 | c.860A>C p.K287T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as COSV99235328; called by muse, mutect2
- KCNH7 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV100036234; called by muse, mutect2
- KCNH8 | c.1414A>G p.I472V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs202127908; called by muse, mutect2, varscan2
- KCNT2 | c.1212G>T p.W404C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99654376; called by muse, mutect2, varscan2
- KDM4A | c.2423T>C p.V808A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100969521; called by muse, mutect2, varscan2
- KIAA0408 | c.1804A>C p.S602R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100846955; called by muse, mutect2
- KIAA1109 | c.9005A>C p.K3002T | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99165266; called by muse, mutect2
- KIAA1109 | c.9877G>A p.D3293N | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99165298; called by muse, mutect2
- KIF26B | c.3368A>T p.E1123V | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV100832666; called by muse, mutect2, varscan2
- KIF4A | c.3452G>A p.G1151E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV100978643; called by muse, mutect2, varscan2
- KLF7 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV58744984; called by muse, mutect2
- KLHL1 | c.186A>T p.R62S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV100917462; called by muse, mutect2, varscan2
- KLHL41 | c.755T>G p.I252S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1480711711, COSV99500416; called by muse, mutect2, varscan2
- KMT2C | c.3476T>G p.I1159S | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV100072764; called by muse, mutect2
- KYAT3 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs930138573, COSV99556418; called by muse, mutect2
- LAD1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.316); catalogued as COSV100943871; called by muse, mutect2, varscan2
- LAG3 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.233); catalogued as rs751673910, COSV99179952; called by muse, mutect2, varscan2
- LAMB1 | c.5100A>C p.K1700N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV99227225; called by muse, mutect2
- LAMB1 | c.2350G>T p.V784L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.131); catalogued as COSV55968153, COSV99741012; called by muse, mutect2
- LAMC1 | c.1445T>G p.F482C | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99279735; called by muse, mutect2, varscan2
- LEPR | c.2031G>C p.Q677H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100756596; called by muse, mutect2, varscan2
- LETM1 | c.911A>T p.E304V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100245487; called by muse, mutect2
- LIMA1 | c.1649A>C p.K550T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100372496; called by muse, mutect2, varscan2
- LIX1L | c.544A>C p.I182L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100811071; called by muse, mutect2
- LRIG3 | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100292674, COSV57870737; called by muse, mutect2, varscan2
- LRP1 | c.3803A>G p.K1268R | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.321); catalogued as COSV99676165; called by muse, mutect2
- LRP1B | c.12647C>A p.S4216* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101254843; called by muse, mutect2
- LRP1B | c.7514-1G>T p.X2505_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as rs1284978290, COSV101252993; called by mutect2, varscan2
- LRRC66 | c.2103T>A p.S701R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV100602994; called by muse, mutect2, varscan2
- LRRC8B | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100446599; called by muse, mutect2, varscan2
- LRRTM3 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.762); catalogued as rs760076742, COSV100791732; called by muse, mutect2, varscan2
- LTB4R | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99350808; called by muse, mutect2, varscan2
- LUZP4 | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV100904855; called by muse, mutect2
- LY6G6F-LY6G6D | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as COSV101012206; called by muse, mutect2
- LYAR | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as COSV100603503, COSV58642452; called by muse, mutect2, varscan2
- MAB21L3 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV101046396; called by muse, mutect2, varscan2
- MACF1 | c.4931A>C p.E1644A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99244995; called by muse, mutect2
- MAGEA6 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs782564930, COSV100262851, COSV100262855; called by muse, mutect2, varscan2
- MAGED2 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99514608; called by muse, mutect2, varscan2
- MAGI1 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441425, COSV58334533; called by muse, mutect2, varscan2
- MANBA | c.1673A>G p.E558G (on ENST00000642252; = p.E512G on NM_005908.4) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV99898819; called by muse, mutect2
- MAP3K21 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.334); catalogued as COSV64041641; called by muse, mutect2
- MAPK7 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs773329608, COSV100218956; called by muse, mutect2
- MARK1 | c.1010-1G>A p.X337_splice | Splice Site (SNP) | VAF 12/151 reads (8%) | catalogued as COSV100857309; called by muse, mutect2
- MAT1A | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100944449; called by muse, mutect2
- MCF2 | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100644833; called by muse, mutect2
- MDM2 | c.1156_1158del p.D386del | In Frame Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs1434404181; called by pindel, varscan2
- MDN1 | c.10078C>G p.R3360G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV101021453; called by muse, mutect2, varscan2
- MECOM | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1439121848, COSV101527928; called by muse, mutect2, varscan2
- MED19 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99762430; called by muse, mutect2, varscan2
- MEGF9 | c.1267A>T p.I423F | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100879418; called by muse, mutect2, varscan2
- METTL4 | c.1394T>G p.F465C | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100170632; called by muse, mutect2
- MIOS | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100402813; called by muse, mutect2, varscan2
- MMP27 | c.583T>G p.F195V | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99498473; called by muse, mutect2
- MMRN1 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1027844357, COSV99307255; called by muse, mutect2, varscan2
- MORC4 | c.1298T>G p.L433R | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99717295; called by muse, mutect2
- MRGPRD | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs761624574, COSV58423941; called by muse, mutect2, varscan2
- MRGPRX4 | c.845A>C p.Q282P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100049743; called by mutect2, varscan2
- MROH2B | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV101270728; called by muse, mutect2, varscan2
- MSH6 | c.2075A>C p.K692T | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); catalogued as COSV99316138; called by muse, mutect2
- MSN | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100814246, COSV64304210; called by muse, mutect2
- MTG2 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100895174; called by muse, mutect2, varscan2
- MTM1 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.396); catalogued as COSV100080511; called by muse, mutect2
- MTRR | c.373G>T p.D125Y (on ENST00000264668; = p.D98Y on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99241807; called by muse, mutect2, varscan2
- MUC16 | c.31645A>T p.T10549S | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV101200145; called by muse, mutect2, varscan2
- MUC16 | c.23147C>T p.P7716L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV67467966; called by muse, mutect2
- MUC16 | c.18595G>T p.V6199F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101200146; called by muse, mutect2, varscan2
- MUC16 | c.17971G>T p.G5991C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.623); catalogued as rs1353387311, COSV101200147, COSV67473496; called by muse, mutect2, varscan2
- MUC16 | c.14871C>A p.N4957K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as COSV101200148; called by muse, mutect2, varscan2
- MUC17 | c.12328A>G p.T4110A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.094); catalogued as COSV100071873; called by muse, mutect2
- MXRA5 | c.2867C>T p.T956I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV99477382; called by muse, mutect2, varscan2
- MYH6 | c.4843A>G p.R1615G | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100676678; called by muse, mutect2, varscan2
- MYH8 | c.3697G>T p.D1233Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101238288; called by muse, mutect2, varscan2
- MYH9 | c.5512C>T p.R1838C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272298108, COSV53386065; called by muse, mutect2, varscan2
- MYLK3 | c.99C>A p.N33K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV67365103; called by muse, mutect2, varscan2
- MYOCD | c.2245+4del | Splice Region (DEL) | VAF 6/22 reads (27%) | catalogued as COSV58500706; called by mutect2, pindel*, varscan2
- NAA15 | c.1727A>T p.E576V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV99649639; called by muse, mutect2, varscan2
- NADK2 | c.780A>C p.E260D (on ENST00000381937 / NM_001085411.3; = p.E97D on NM_153013.4) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV99237559; called by muse, mutect2, varscan2
- NAP1L2 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100999213; called by muse, mutect2, varscan2
- NAV3 | c.6547C>A p.P2183T (on ENST00000397909 / NM_001024383.2; = p.P2161T on NM_014903.6) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181056160, COSV99891901; called by muse, mutect2, varscan2
- NCAN | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV53058867; called by muse, mutect2
- NCAPG | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52269712; called by muse, mutect2
- NCBP1 | c.1997T>C p.L666P | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100910631; called by muse, mutect2
- NCOA3 | c.3057A>C p.Q1019H | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV100507670; called by muse, mutect2
- NCOA5 | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as COSV99275686; called by muse, mutect2
- NES | c.3060A>C p.K1020N | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100957889; called by muse, mutect2, varscan2
- NEURL4 | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100224348, COSV59757364; called by muse, mutect2, varscan2
- NFKBIZ | c.1159G>T p.G387W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100397088, COSV58200638; called by muse, mutect2, varscan2
- NINL | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV99625528; called by muse, mutect2
- NIPBL | c.6101A>C p.K2034T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV99240972; called by muse, mutect2
- NLRC4 | c.2168C>A p.P723H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100707413; called by muse, varscan2
- NME8 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99553421; called by muse, mutect2
- NME8 | c.1261T>C p.F421L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV99553422; called by muse, mutect2, varscan2
- NMUR2 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV99676979; called by muse, mutect2, varscan2
- NNT | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV99239049; called by muse, mutect2, varscan2
- NNT | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.609); catalogued as rs1294112684, COSV99239052; called by muse, mutect2, varscan2
- NOS1AP | c.454-1G>T p.X152_splice | Splice Site (SNP) | VAF 13/100 reads (13%) | catalogued as rs1242977620, COSV100723352; called by muse, mutect2, varscan2
- NPAS4 | c.1499A>G p.Q500R | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100215053; called by muse, mutect2
- NR3C1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51546030; called by muse, mutect2
- NRAP | c.3905T>C p.I1302T (on ENST00000359988 / NM_001322945.2; = p.I1267T on NM_006175.4) | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs762544690, COSV100748464; called by muse, mutect2, varscan2
- NRP2 | c.2617A>G p.S873G (on ENST00000360409 / NM_201266.2; = p.S868G on NM_003872.3) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100760913; called by muse, mutect2
- NSG2 | c.214-2A>T p.X72_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100292840, COSV57460068; called by muse, mutect2, varscan2
- NUP210 | c.3773A>G p.K1258R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99596353; called by muse, mutect2
- NUP210L | c.5264G>A p.R1755K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV99668269; called by muse, mutect2, varscan2
- NXPH2 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99740793; called by muse, mutect2, varscan2
- OGT | c.1937C>A p.A646D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101035472; called by muse, mutect2, varscan2
- OR10AD1 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100046831; called by muse, mutect2, varscan2
- OR11G2 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639972; called by muse, mutect2, varscan2
- OR1J2 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100093279; called by muse, mutect2, varscan2
- OR2A12 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV101283173; called by muse, mutect2
- OR2T6 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1392432642, COSV100861572; called by muse, mutect2
- OR4A15 | c.157del p.L53Wfs*15 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as COSV59037495; called by mutect2, varscan2
- OR4C46 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV100060761; called by muse, mutect2
- OR4M1 | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs778692665, COSV60064156; called by muse, mutect2, varscan2
- OR4N2 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as rs1401460822, COSV100269673; called by muse, mutect2, varscan2
- OR51B6 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1315730841, COSV100971427; called by muse, mutect2, varscan2
- OR51Q1 | c.627T>G p.I209M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.78); catalogued as COSV100332959; called by muse, mutect2, varscan2
- OR51S1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs143553379, COSV59057098; called by muse, mutect2, varscan2
- OR52K2 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57834665, COSV57834781; called by muse, mutect2, varscan2
- OR52R1 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617741; called by muse, mutect2, varscan2
- OR5V1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149477718, COSV65830482; called by muse, mutect2, varscan2
- OR6C68 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as rs1215741200, COSV65564122; called by muse, mutect2, varscan2
- OR8G5 | c.700A>T p.R234W | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100422485; called by muse, mutect2, varscan2
- OXCT2 | c.1437A>T p.K479N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV100560305; called by muse, mutect2
- OXER1 | c.160T>A p.S54T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.01); catalogued as rs1487038195, COSV99685410; called by muse, mutect2
- PACC1 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99801230; called by muse, mutect2
- PALM2AKAP2 | c.993G>C p.Q331H (on ENST00000259318 / NM_001136562.3; = p.Q562H on NM_007203.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1055841311, COSV99395326; called by muse, mutect2, varscan2
- PALMD | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99586442; called by muse, mutect2
- PAQR9 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as COSV100503826, COSV61418258; called by muse, mutect2, varscan2
- PARP3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99232488; called by muse, mutect2
- PCDH11X | c.2774C>A p.P925H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100012307; called by muse, mutect2, varscan2
- PCDHA2 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100973923; called by muse, mutect2, varscan2
- PCDHA3 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as rs782008104, COSV100973924; called by muse, mutect2, varscan2
- PCDHA7 | c.2030A>T p.K677M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs782551765, COSV100970806; called by muse, mutect2, varscan2
- PCDHB2 | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV99523249; called by muse, mutect2, varscan2
- PCDHB5 | c.198G>C p.M66I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99167990; called by muse, mutect2, varscan2
- PCDHGA6 | c.1520T>A p.I507N | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1561568850; called by muse, mutect2
- PDAP1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV56117203; called by muse, mutect2
- PDE3A | c.2608G>C p.A870P | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100762238, COSV100762421; called by muse, mutect2, varscan2
- PDE9A | c.1661A>G p.K554R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as COSV99371680; called by muse, mutect2
- PDIA5 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV100299472; called by muse, mutect2
- PDXDC1 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as COSV100363219; called by muse, mutect2, varscan2
- PDZRN4 | c.1924G>T p.E642* (on ENST00000402685 / NM_001164595.2; = p.E384* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV54201500; called by muse, mutect2, varscan2
- PEAK1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100433096; called by muse, mutect2
- PGAP1 | c.1961G>T p.W654L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100698231; called by muse, mutect2
- PGBD2 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100252079; called by muse, mutect2, varscan2
- PHF14 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV101301816; called by muse, mutect2
- PHF2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs760648436, COSV100823205, COSV63682994; called by muse, varscan2
- PHLDB2 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101208560; called by muse, mutect2
- PITPNM1 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.102); catalogued as COSV56873339; called by muse, mutect2, varscan2
- PITPNM1 | c.550G>C p.G184R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100039415; called by muse, mutect2, varscan2
- PKD1 | c.12376G>A p.D4126N (on ENST00000262304 / NM_001009944.3; = p.D4125N on NM_000296.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359957327, COSV51910846; called by muse, mutect2
- PKN2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100281636; called by muse, mutect2
- PKNOX1 | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99372775, COSV99372904; called by muse, mutect2, varscan2
- PLAT | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99535249; called by muse, mutect2
- PLEKHG3 | c.662A>G p.E221G (on ENST00000394691; = p.E277G on NM_001308147.2) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906692; called by muse, mutect2
- PLEKHM3 | c.1703A>T p.Q568L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV101216645; called by muse, mutect2, varscan2
- PLEKHM3 | c.1691A>C p.K564T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV101216646; called by muse, mutect2
- POGK | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV100902501, COSV63311422; called by muse, mutect2, varscan2
- POU4F1 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV101020564; called by muse, mutect2, varscan2
- PPIP5K2 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 12/143 reads (8%) | catalogued as rs147568161; called by muse, mutect2
- PPP1CB | c.880-2A>C p.X294_splice | Splice Site (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99941869; called by muse, mutect2
- PPP2R2C | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100160609; called by muse, mutect2, varscan2
- PPP3R2 | c.89T>C p.L30S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100701565; called by muse, mutect2, varscan2
- PPP4R3B | c.1307A>C p.Q436P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV99702132; called by muse, mutect2
- PRDM4 | c.740A>T p.D247V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99946624; called by muse, mutect2, varscan2
- PRELID2 | c.97A>C p.N33H (on ENST00000334744 / NM_182960.4; = p.N4H on NM_138492.6) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV100597180; called by muse, mutect2
- PREX1 | c.3816C>A p.S1272R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs200774333, COSV100906449; called by muse, mutect2, varscan2
- PREX1 | c.1445A>T p.K482M | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100906451; called by muse, mutect2
- PRKCI | c.1448G>C p.R483P | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV55516956, COSV99855928; called by muse, mutect2, varscan2
- PROS1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV62399071; called by muse, mutect2
- PRPSAP1 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1281181444, COSV100221730; called by muse, mutect2
- PRR19 | c.153T>G p.D51E | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100003915; called by muse, mutect2, varscan2
- PRSS1 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100298057; called by muse, mutect2, varscan2
- PSMD12 | c.166A>T p.T56S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); catalogued as COSV100635358; called by muse, mutect2, varscan2
- PSORS1C1 | c.167+1G>T p.X56_splice | Splice Site (SNP) | VAF 23/102 reads (23%) | catalogued as COSV99456135; called by muse, varscan2
- PTGIR | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV99354996; called by muse, mutect2
- PTK2 | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100570406, COSV61785314; called by muse, mutect2
- PTPRC | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100722746; called by muse, mutect2, varscan2
- PTPRD | c.2730G>T p.E910D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100645140, COSV61941955; called by muse, mutect2, varscan2
- PTPRR | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51728591; called by muse, mutect2
- PTPRT | c.3704C>A p.A1235E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100628040; called by muse, mutect2, varscan2
- PWWP3B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV61798513; called by muse, mutect2, varscan2
- PXYLP1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV53893291; called by muse, mutect2
- PYHIN1 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV100932361, COSV100932412; called by muse, mutect2
- QRICH2 | c.2300A>G p.Q767R | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99429348; called by muse, mutect2
- QSOX2 | c.725T>A p.L242Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100699783; called by muse, mutect2
- RAB33A | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57061152; called by muse, mutect2, varscan2
- RAB8A | c.525A>C p.K175N | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99507303; called by muse, mutect2
- RABGAP1L | c.1890A>T p.L630F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270955; called by muse, mutect2, varscan2
- RAD17 | c.1648T>G p.F550V (on ENST00000380774 / NM_133339.2; = p.F539V on NM_002873.1) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV99281548; called by muse, mutect2, varscan2
- RAD21 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV52065172; called by muse, mutect2, varscan2
- RAPGEF3 | c.2516T>C p.F839S (on ENST00000389212; = p.F797S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406437; called by muse, mutect2
- RBM12B | c.2118T>G p.D706E | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.475); catalogued as COSV101234520; called by muse, mutect2, varscan2
- RCOR1 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV99217543; called by muse, mutect2, varscan2
- RECQL5 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99502867; called by muse, mutect2
- REG1B | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.168); catalogued as COSV100521409; called by muse, mutect2, varscan2
- RELN | c.4882G>A p.V1628I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.925); catalogued as rs1436133395, COSV100633971; called by muse, mutect2, varscan2
- REPS2 | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100381253; called by muse, mutect2, varscan2
- REV3L | c.5960T>G p.V1987G | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100725295; called by muse, mutect2
- RGS8 | c.128A>C p.K43T (on ENST00000367556 / NM_001369564.2; = p.K61T on NM_033345.3) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV99276709; called by muse, mutect2, varscan2
- RHEX | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs782360608, COSV100520158; called by muse, mutect2, varscan2
- RNASE10 | c.11A>C p.N4T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100116159; called by muse, mutect2, varscan2
- RNF111 | c.2306A>G p.H769R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100789086; called by muse, mutect2
- RPGRIP1 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV52852640, COSV99251191; called by muse, mutect2, varscan2
- RRP8 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV99601934; called by muse, mutect2, varscan2
- RSF1 | c.3614G>A p.R1205K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV100407325; called by muse, mutect2, varscan2
- RTN4 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100463333; called by muse, mutect2
- RUFY2 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV101175915; called by muse, mutect2, varscan2
- RXFP1 | c.1899A>G p.I633M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100313824; called by muse, mutect2, varscan2
- RYR3 | c.3790G>T p.D1264Y | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV101212962, COSV66809812; called by muse, mutect2, varscan2
- S100P | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs1297524989; called by muse, mutect2
- SALL1 | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.162); catalogued as COSV99174556; called by muse, mutect2, varscan2
- SAMD14 | c.898A>T p.K300* (on ENST00000330175 / NM_001257359.2; = p.K328* on NM_174920.4) | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99142976; called by muse, mutect2, varscan2
- SBF1 | c.3364G>T p.V1122L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as rs1193153809, COSV100817813; called by muse, mutect2, varscan2
- SCARB2 | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.401); catalogued as COSV99357966; called by muse, mutect2
- SCN11A | c.1859T>G p.F620C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181766; called by muse, mutect2, varscan2
- SCN4A | c.3328A>G p.I1110V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as rs1285493044, COSV101438516; called by muse, mutect2, varscan2
- SCUBE2 | c.3087A>T p.*1029Cext*40 (on ENST00000649792 / NM_001367977.2; = p.*972Cext*40 on NM_020974.3) | Nonstop Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100496727; called by muse, mutect2
- SDAD1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV100668635; called by muse, mutect2
- SDCBP2 | c.508C>T p.Q170* (on ENST00000339987 / NM_001199784.1; = p.Q85* on NM_015685.5) | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV60589267; called by muse, mutect2
- SEC14L3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV99307181; called by muse, mutect2, varscan2
- SEC24A | c.1015A>G p.S339G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100524551; called by muse, mutect2, varscan2
- SEMA6D | c.1932G>A p.K644= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100317131; called by muse, mutect2, varscan2
- SERPINA7 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1190423059, COSV100568350; called by muse, mutect2, varscan2
- SERPINB11 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV101236258; called by muse, mutect2, varscan2
- SETX | c.5473A>T p.T1825S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99810013; called by muse, mutect2, varscan2
- SF3B1 | c.531A>C p.K177N | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100134894; called by muse, mutect2
- SHD | c.980A>C p.E327A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100010324; called by muse, mutect2, varscan2
- SHLD2 | c.1750T>G p.F584V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100079235; called by muse, mutect2
- SHTN1 | c.1110C>T p.I370= | Splice Region (SNP) | VAF 7/60 reads (12%) | catalogued as rs1183907248, COSV99598999; called by muse, mutect2, varscan2
- SLC16A1 | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as rs776906225, COSV100856001; called by muse, mutect2, varscan2
- SLC16A12 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100370271; called by muse, mutect2
- SLC17A3 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1347548292, COSV100399235; called by muse, mutect2, varscan2
- SLC22A13 | c.11T>G p.F4C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100314581; called by muse, mutect2, varscan2
- SLC4A8 | c.1642T>G p.L548V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); catalogued as COSV100177039; called by muse, mutect2, varscan2
- SLC51A | c.521+2T>A p.X174_splice | Splice Site (SNP) | VAF 4/57 reads (7%) | catalogued as COSV99580259; called by muse, mutect2
- SLC5A9 | c.900C>A p.V300= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as rs1483272328, COSV99361743; called by muse, mutect2, varscan2
- SLC9A5 | c.1412A>G p.E471G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100237364; called by muse, mutect2
- SLFN12 | c.391A>T p.I131L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100513111; called by muse, mutect2, varscan2
- SMARCA2 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | catalogued as COSV100571223; called by muse, mutect2
- SMCP | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.373); catalogued as COSV100908358; called by muse, mutect2, varscan2
- SMG1 | c.3008A>T p.N1003I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.278); catalogued as COSV101246175; called by muse, mutect2, varscan2
- SMG8 | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99958889; called by muse, mutect2, varscan2
- SNRNP200 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV100107670; called by muse, mutect2
- SNRNP200 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100107675; called by muse, mutect2
- SPAM1 | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99773108; called by muse, mutect2
- SPANXD | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.681); catalogued as rs782615325, COSV65153296; called by muse, mutect2
- SPATA18 | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99730679; called by muse, mutect2, varscan2
- SPHKAP | c.4019C>T p.S1340F | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100764200; called by muse, mutect2
- SPIRE1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 6/111 reads (5%) | catalogued as COSV100563743; called by muse, mutect2
- SPTA1 | c.5364G>T p.E1788D | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100935106; called by muse, mutect2, varscan2
- SRP54 | c.1373T>G p.L458W | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99392651; called by muse, mutect2
- SSPOP | n.844C>T | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100022609; called by muse, mutect2, varscan2
- ST3GAL3 | c.736T>A p.F246I (on ENST00000361392 / NM_174964.4; = p.F231I on NM_006279.5) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99495508; called by muse, mutect2, varscan2
- STAB1 | c.2520G>T p.Q840H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as rs1261015651, COSV100401841, COSV58733400; called by muse, mutect2, varscan2
- STK10 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99451708; called by muse, mutect2, varscan2
- STS | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99481324; called by muse, mutect2, varscan2
- STYXL2 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99609379; called by muse, mutect2
- SUPT6H | c.3199A>G p.R1067G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100112494; called by muse, mutect2
- SYNE2 | c.16530A>C p.K5510N | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV100647867; called by muse, mutect2
- SYNE2 | c.16864A>G p.N5622D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100647869; called by muse, mutect2
- SZRD1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100981518; called by muse, mutect2, varscan2
- TAF1 | c.1123G>T p.D375Y (on ENST00000373790 / NM_138923.4; = p.D396Y on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99336018; called by muse, mutect2, varscan2
- TAF1L | c.3679A>C p.K1227Q | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV99644835; called by muse, mutect2
- TAF5 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100674699; called by muse, mutect2
- TAF5L | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV51079010, COSV51083666; called by muse, mutect2, varscan2
- TAOK3 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101183580; called by muse, mutect2, varscan2
- TAS2R41 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101281495; called by muse, mutect2, varscan2
- TAS2R41 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101281496; called by muse, mutect2, varscan2
- TAX1BP3 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99251357; called by muse, varscan2
- TC2N | c.1436A>C p.K479T | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100562947; called by muse, mutect2
- TCEAL6 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101035977; called by muse, mutect2, varscan2
- TENM2 | c.2675del p.G892Afs*8 (on ENST00000518659 / NM_001122679.2; = p.G660Afs*8 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV101318818; called by pindel, varscan2
- TENM4 | c.6238C>T p.R2080C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1447189784, COSV99575517; called by muse, mutect2
- TEP1 | c.2098-2A>G p.X700_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as rs768380701, COSV99402577; called by mutect2, varscan2
- TEX15 | c.7153C>A p.P2385T (on ENST00000256246; = p.P2768T on NM_001350162.2) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV56348858, COSV99821478; called by muse, mutect2, varscan2
- THBS4 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100644314; called by muse, mutect2
- TIGD3 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99361728; called by muse, mutect2, varscan2
- TIPRL | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV100893288; called by muse, mutect2
- TMEM174 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99703782; called by muse, mutect2, varscan2
- TMEM185A | c.482A>C p.D161A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100383072, COSV57560790; called by muse, mutect2, varscan2
- TMEM198 | c.945G>T p.P315= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as rs1393645661, COSV99524885, COSV99525063; called by muse, mutect2
- TMEM218 | c.111-2A>T p.X37_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | catalogued as COSV54445522; called by muse, mutect2
- TMEM241 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.181); catalogued as COSV101271744; called by muse, mutect2
- TMEM37 | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50029653, COSV99191610; called by muse, mutect2
- TNFAIP3 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); catalogued as COSV52803174, COSV99396854; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4024A>C p.M1342L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100836090; called by muse, mutect2
- TNKS2 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as rs1279524523, COSV100861113; called by muse, mutect2, varscan2
- TP63 | c.917T>G p.F306C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287226; called by muse, mutect2
- TRAF3 | c.1442A>T p.E481V | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100693627; called by muse, mutect2
- TRAIP | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100513260; called by muse, mutect2, varscan2
- TRIM4 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100584318; called by muse, mutect2
- TRPA1 | c.1217T>A p.V406E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100084366; called by muse, mutect2, varscan2
- TRPM6 | c.5074G>T p.G1692* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100666497; called by muse, mutect2
- TRPV1 | c.2363G>T p.W788L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99438838; called by muse, mutect2, varscan2
- TSG101 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV99324034; called by muse, mutect2, varscan2
- TSHZ3 | c.3208G>T p.D1070Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs767075068, COSV53682359, COSV99551824; called by muse, mutect2, varscan2
- TSHZ3 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs201870186, COSV53666964, COSV99551825; called by muse, mutect2, varscan2
- TSPEAR | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1277378753, COSV59952918; called by muse, mutect2, varscan2
- TTF1 | c.2145A>C p.K715N | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100524743; called by muse, mutect2
- TTF1 | c.894A>C p.Q298H | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100524744; called by muse, mutect2
- TTLL5 | c.325T>G p.L109V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99709658; called by muse, mutect2, varscan2
- TTN | c.101429C>T p.A33810V (on ENST00000591111; = p.A26386V on NM_003319.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | PolyPhen benign (0); catalogued as COSV60330973; called by muse, mutect2, varscan2
- TTN | c.76148C>T p.S25383L (on ENST00000591111; = p.S17959L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/154 reads (5%) | PolyPhen probably damaging (0.996); catalogued as rs868703911, COSV100613010, COSV100617126; called by muse, mutect2
- TYK2 | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99314863; called by muse, mutect2
- TYR | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV99634450; called by mutect2, varscan2
- UBA6 | c.2461G>T p.E821* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | catalogued as rs1449277639, COSV99079734; called by muse, mutect2, varscan2
- UBR4 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV100921060; called by muse, mutect2, varscan2
- UCP3 | c.797A>G p.Q266R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100012992, COSV58369023; called by muse, mutect2, varscan2
- ULK4 | c.1212C>A p.D404E | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV100093140; called by muse, mutect2, varscan2
- USH1C | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as CM0911278, COSV99140283; called by muse, mutect2, varscan2
- USP12 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV56658490; called by muse, mutect2
- USP9X | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100199439; called by muse, mutect2
- VARS2 | c.528A>C p.Q176H | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99461918; called by muse, mutect2
- VCPIP1 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100125666; called by muse, mutect2
- VCPIP1 | c.1041G>A p.W347* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100125668; called by muse, mutect2
- VPS13A | c.2563C>T p.L855F | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100652955; called by muse, mutect2
- VPS41 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV100053967; called by muse, mutect2
- VPS45 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV100964914; called by muse, mutect2, varscan2
- VWA8 | c.1211A>C p.K404T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99864344; called by muse, mutect2
- WDR59 | c.2758T>A p.F920I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as rs771758499, COSV100049433; called by mutect2, varscan2
- WWC2 | c.3272G>T p.R1091M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101330962; called by muse, mutect2, varscan2
- XKR3 | c.686A>T p.K229M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV100509286, COSV58886200; called by muse, mutect2, varscan2
- XPO7 | c.3255G>A p.M1085I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV99381449; called by muse, mutect2
- ZBTB41 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV66358778, COSV66359174; called by muse, mutect2, varscan2
- ZEB2 | c.3152G>T p.G1051V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356232; called by muse, mutect2, varscan2
- ZFP64 | c.925A>T p.K309* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as COSV99402627; called by muse, mutect2, varscan2
- ZMIZ2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV54810414; called by muse, mutect2
- ZNF141 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1553853890, COSV99549750; called by muse, mutect2, varscan2
- ZNF165 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV101055952; called by muse, mutect2, varscan2
- ZNF23 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.102); catalogued as COSV100612191; called by muse, mutect2
- ZNF232 | c.412T>C p.W138R | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV100005712; called by muse, mutect2
- ZNF235 | c.1545T>G p.F515L | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV99349509; called by muse, mutect2
- ZNF236 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1278297024, COSV99470528; called by muse, mutect2, varscan2
- ZNF331 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99467453; called by muse, mutect2
- ZNF418 | c.132G>T p.L44= | Splice Region (SNP) | VAF 15/52 reads (29%) | catalogued as COSV101268946; called by muse, mutect2, varscan2
- ZNF423 | c.1573T>G p.F525V (on ENST00000563137 / NM_001379286.1; = p.F517V on NM_015069.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV99282135; called by muse, mutect2
- ZNF514 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV99727780; called by muse, mutect2
- ZNF514 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99727782; called by muse, mutect2, varscan2
- ZNF518A | c.4146A>T p.R1382S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100283568, COSV60152625; called by muse, mutect2
- ZPLD1 | c.1116C>A p.S372R (on ENST00000466937 / NM_001329788.1; = p.S388R on NM_175056.2) | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100083294; called by muse, mutect2, varscan2
- ZSCAN22 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 10/121 reads (8%) | catalogued as COSV100308387; called by muse, mutect2
- ZSWIM8 | c.3897G>T p.W1299C (on ENST00000605216 / NM_001242487.2; = p.W1304C on NM_015037.3) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100014055; called by muse, mutect2, varscan2
- ADA2 | c.323-1G>T p.X108_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ADAMTS6 | c.1490C>A p.T497N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2
- ADGRV1 | c.7783T>C p.F2595L | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.217); called by muse, mutect2
- AFM | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- ALPK1 | c.2756A>C p.N919T | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2
- AOPEP | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); called by muse, mutect2
- C6orf89 | c.580G>A p.E194K (on ENST00000373685; = p.E201K on NM_152734.4) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2
- CAPRIN1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.202); called by muse, mutect2
- CCT4 | c.1052T>G p.F351C | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CTSG | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.162); called by muse, mutect2
- DOLK | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- FNDC4 | c.166del p.T56Lfs*37 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- GALNT18 | c.586A>T p.S196C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRM5 | c.2697G>T p.M899I | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.011); called by muse, mutect2
- HSPA12B | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- IGHV1OR21-1 | c.344G>C p.C115S | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- IGLV4-3 | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- KCNH5 | c.1389T>G p.I463M | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KNTC1 | c.1796A>C p.K599T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- KRTAP10-8 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2
- MAP3K12 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.025); called by muse, mutect2
- MAPT | c.83del p.G28Afs*16 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- MBIP | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MECP2 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- MED17 | c.1039del p.H347Ifs*25 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- METTL2A | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2
- MTHFD2L | c.380T>G p.L127R (on ENST00000395759 / NM_001144978.2; = p.L69R on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NBPF1 | c.2494T>C p.W832R | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NDRG4 | c.233del p.S78Cfs*31 (on ENST00000570248 / NM_001378344.1; = p.S110Cfs*31 on NM_020465.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by mutect2, pindel, varscan2
- NEK3 | c.668del p.P223Rfs*11 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- NLRX1 | c.1762T>A p.Y588N | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.738); called by muse, mutect2
- NUBPL | c.305_313del p.G102_L104del | In Frame Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- PCDHA2 | c.1424T>G p.F475C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2
- PCLO | c.9712del p.E3238Nfs*26 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- PITPNC1 | c.304dup p.L102Pfs*13 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- PITPNC1 | c.305delinsCA p.L102Pfs*13 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2*, pindel, varscan2*
- PLD6 | c.592T>C p.F198L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2
- QSER1 | c.5175A>C p.E1725D (on ENST00000399302; = p.E1854D on NM_001076786.3) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2
- RAB6A | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RTL4 | c.665G>T p.R222M | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- S100A16 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2
- SETD2 | c.6004del p.T2002Qfs*4 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | called by pindel, varscan2*
- SLC38A4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- SRP72 | c.784T>A p.L262I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- STAMBPL1 | c.405A>C p.E135D | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- STXBP5L | c.3342del p.Q1114Hfs*9 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.2033C>A p.P678Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- TIMM8A | c.125T>A p.L42H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2
- TRAV17 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- TSPOAP1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- ZFYVE26 | c.7145A>C p.K2382T | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- ZNF175 | c.1569A>T p.K523N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2
- ZNF536 | c.1869dup p.G624Wfs*47 | Frame Shift Ins (INS) | VAF 30/160 reads (19%) | called by mutect2, pindel, varscan2
- ZNF701 | c.614dup p.L206Afs*11 (on ENST00000301093; = p.L140Afs*11 on NM_018260.3) | Frame Shift Ins (INS) | VAF 22/149 reads (15%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1748A>C p.K583T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ABCC12 | c.2992C>T p.L998= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100252793; called by muse, mutect2
- ADA2 | c.246C>G p.P82= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99376126; called by muse, mutect2, varscan2
- ADAR | c.2430G>T p.V810= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1397449432, COSV99426158; called by muse, mutect2, varscan2
- AHNAK | c.15213C>T p.L5071= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as COSV99947898; called by muse, mutect2
- AHR | c.522A>T p.L174= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV54122973, COSV99619809; called by muse, mutect2, varscan2
- ALPI | c.621T>A p.T207= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV99785967; called by muse, mutect2, varscan2
- ARC | c.1140G>C p.T380= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100751723; called by muse, mutect2
- ARHGEF12 | c.3174T>G p.V1058= | Silent (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- ATF7IP2 | c.1372T>C p.L458= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs1051922271; called by muse, mutect2
- BANP | c.927G>A p.Q309= (on ENST00000286122; = p.Q278= on NM_017869.4) | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV99621684; called by muse, mutect2
- BCO1 | c.636G>A p.G212= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs765733923, COSV99258141; called by muse, mutect2
- BEND5 | c.954C>A p.T318= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV100884125; called by muse, mutect2, varscan2
- BRWD3 | c.3906T>A p.P1302= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100956170; called by muse, mutect2, varscan2
- C12orf54 | c.141G>T p.L47= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as rs1159283551, COSV58361408; called by muse, mutect2, varscan2
- C1QTNF1 | c.465C>T p.P155= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1393447859, COSV100190002; called by muse, mutect2, varscan2
- C1orf87 | c.1470G>T p.L490= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1325614134, COSV100967124, COSV64599162; called by muse, mutect2, varscan2
- CDC42BPA | c.4239C>T p.I1413= (on ENST00000334218 / NM_001366019.2; = p.I1400= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100505597; called by muse, mutect2, varscan2
- CDC42BPB | c.2199C>T p.I733= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV63475444; called by muse, mutect2, varscan2
- CDC42SE1 | c.177T>G p.V59= | Silent (SNP) | VAF 7/200 reads (4%) | catalogued as COSV100603371; called by muse, mutect2
- CEBPZ | c.1755T>G p.A585= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99305261; called by muse, mutect2, varscan2
- CENPP | c.304C>T p.L102= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV100981212; called by muse, mutect2, varscan2
- CFAP47 | c.237C>A p.P79= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52882572, COSV99935203; called by muse, mutect2, varscan2
- CNTNAP2 | c.1395C>A p.A465= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100667136, COSV62267915; called by muse, mutect2, varscan2
- COL1A2 | c.4056T>A p.A1352= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV99800059; called by muse, mutect2
- COQ6 | c.246T>G p.T82= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99473976; called by muse, mutect2, varscan2
- CPT2 | c.1704C>T p.I568= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV99598178; called by muse, mutect2, varscan2
- CSF2RA | c.609C>A p.I203= | Silent (SNP) | VAF 69/376 reads (18%) | catalogued as COSV100817780; called by muse, mutect2, varscan2
- CTNNA2 | c.2805G>A p.K935= (on ENST00000402739 / NM_001282597.3; = p.K887= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV58153180; called by muse, mutect2, varscan2
- CUL9 | c.288T>G p.V96= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99335518; called by muse, mutect2
- DGCR8 | c.1419G>A p.R473= | Silent (SNP) | VAF 10/219 reads (5%) | catalogued as COSV100708008; called by muse, mutect2
- DHX36 | c.1311A>T p.A437= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV100273661; called by muse, mutect2, varscan2
- DISC1 | c.906C>T p.S302= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV99697939; called by muse, mutect2, varscan2
- DMGDH | c.1209C>T p.H403= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs143266258; called by muse, mutect2, varscan2
- DOCK7 | c.2667T>G p.L889= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99224782; called by muse, mutect2, varscan2
- DRD3 | c.213G>T p.L71= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs1176402370, COSV99879493; called by muse, mutect2, varscan2
- EVC | c.861G>T p.G287= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1409202718, COSV99381926; called by muse, varscan2
- FOCAD | c.3351G>T p.L1117= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100620485; called by muse, mutect2, varscan2
- FST | c.798G>T p.R266= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV56814867; called by muse, mutect2, varscan2
- GALNTL5 | c.135T>C p.A45= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101217839; called by muse, mutect2
- GCKR | c.1038A>C p.G346= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as COSV99269158; called by muse, mutect2, varscan2
- GDF5 | c.1104C>T p.T368= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as rs748907807, COSV65500314; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GLIS1 | c.945C>A p.T315= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100390206; called by muse, mutect2, varscan2
- GLT8D2 | c.270T>C p.T90= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs375611093, COSV100674058; called by muse, mutect2, varscan2
- GLUD2 | c.321G>T p.R107= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs1489645825, COSV100046859; called by muse, mutect2, varscan2
- GPM6A | c.696T>C p.L232= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99704266; called by muse, mutect2
- GPR6 | c.594C>A p.G198= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1212141224, COSV51574162, COSV99254380; called by muse, mutect2
- GRIN2B | c.3873G>A p.Q1291= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1450587190, COSV101663069, COSV74208153; called by muse, mutect2
- GRM3 | c.549C>G p.R183= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV100862600; called by muse, mutect2
- GTF3C4 | c.2343G>A p.Q781= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV100936026; called by muse, mutect2, varscan2
- HUWE1 | c.834G>A p.Q278= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99472740; called by muse, mutect2, varscan2
- ICE2 | c.21A>T p.I7= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV99831595; called by muse, mutect2, varscan2
- IGSF22 | c.2619A>G p.R873= (on ENST00000319338; = p.R974= on NM_173588.4) | Silent (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- IGSF9 | c.3456C>T p.F1152= (on ENST00000368094 / NM_001135050.2; = p.F1136= on NM_020789.4) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV57422875; called by muse, mutect2, varscan2
- IRS4 | c.3711T>A p.T1237= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV100929597; called by muse, mutect2, varscan2
- IRS4 | c.2514G>T p.G838= | Silent (SNP) | VAF 12/270 reads (4%) | catalogued as COSV100929598; called by muse, mutect2
- ITIH6 | c.3832C>T p.L1278= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs750318630, COSV99513424; called by mutect2, varscan2
- ITPR2 | c.6459G>T p.R2153= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV101190026; called by muse, mutect2, varscan2
- KDSR | c.642T>A p.A214= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100430264; called by muse, mutect2, varscan2
- KIAA1191 | c.456C>T p.L152= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- KIAA2026 | c.1116G>T p.A372= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101199086, COSV67355397; called by muse, mutect2, varscan2
- KLK9 | c.588C>A p.G196= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- LAMC3 | c.456C>G p.R152= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV63089470, COSV63094410; called by muse, mutect2, varscan2
- LILRA1 | c.1251C>A p.L417= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV99251948; called by muse, mutect2, varscan2
- LRRC39 | c.423C>T p.I141= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as COSV100734490, COSV61584125; called by muse, mutect2
- MAGEB3 | c.855G>A p.K285= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- MAGEL2 | c.2472C>A p.P824= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100045990, COSV58567351; called by muse, mutect2, varscan2
- MDN1 | c.1296G>A p.L432= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV65517489; called by muse, mutect2
- MMEL1 | c.711C>T p.I237= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99983939; called by muse, mutect2
- MRPL17 | c.351G>T p.R117= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99996880; called by muse, mutect2, varscan2
- MTUS2 | c.2379A>T p.S793= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101462266; called by muse, mutect2, varscan2
- MUC16 | c.40986C>A p.T13662= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV101109928; called by muse, mutect2, varscan2
- MUC3A | c.7143C>T p.T2381= | Silent (SNP) | VAF 40/248 reads (16%) | catalogued as rs1473422880; called by muse, mutect2, varscan2
- MYO5C | c.3177G>T p.A1059= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs1156614177, COSV99954886; called by muse, mutect2
- NALCN | c.75G>C p.S25= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs374635988, COSV51922893; called by muse, mutect2, varscan2
- NCF2 | c.183C>A p.T61= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100838907; called by muse, mutect2, varscan2
- NLRC5 | c.2538G>T p.T846= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99346514, COSV99347524; called by muse, mutect2, varscan2
- NPEPPS | c.1677T>C p.I559= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV100443759; called by muse, mutect2
- NWD1 | c.4173T>C p.V1391= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV100342841; called by muse, mutect2
- OLFML2B | c.1908G>A p.L636= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99668527; called by muse, mutect2, varscan2
- OR10AD1 | c.849C>A p.T283= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100046836; called by muse, mutect2, varscan2
- OR2L3 | c.84C>A p.I28= | Silent (SNP) | VAF 44/203 reads (22%) | catalogued as COSV100741985, COSV100742083; called by muse, mutect2, varscan2
- OR2T33 | c.429C>G p.T143= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- OR4D2 | c.576C>A p.T192= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV101613860; called by muse, mutect2, varscan2
- OR4P4 | c.618G>A p.L206= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100111757; called by muse, mutect2, varscan2
- OR5D18 | c.759T>C p.H253= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs779846050, COSV100450727; called by muse, mutect2, varscan2
- OR5L1 | c.327C>A p.V109= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV100450079; called by muse, mutect2, varscan2
- OR5T1 | c.549C>A p.S183= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV100479073; called by muse, mutect2, varscan2
- OR8H1 | c.213C>G p.L71= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV100477156; called by muse, mutect2
- PADI2 | c.1446C>G p.P482= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs750101345, COSV100970975; called by muse, mutect2, varscan2
- PCNP | c.270T>G p.L90= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99504059; called by muse, mutect2
- PER3 | c.3507A>G p.Q1169= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs774487592, COSV100728375; called by mutect2, varscan2
- PIEZO2 | c.6949C>A p.R2317= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs1329879893, COSV53290118, COSV99555074; called by muse, mutect2, varscan2
- PIM2 | c.39C>T p.P13= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99332044; called by muse, mutect2
- PITPNB | c.714C>T p.L238= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs967639074; called by muse, mutect2
- PKHD1L1 | c.438A>T p.P146= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV101006280; called by muse, mutect2, varscan2
- PLG | c.1333A>C p.R445= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV51985999; called by muse, mutect2
- PMPCA | c.366A>C p.R122= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- PRAMEF20 | c.1191G>T p.L397= | Silent (SNP) | VAF 42/308 reads (14%) | called by muse, mutect2, varscan2
- PREX1 | c.2568G>T p.V856= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs747999466, COSV100906450; called by muse, mutect2, varscan2
- PTBP2 | c.81A>G p.L27= (on ENST00000426398 / NM_001300986.2; = p.L19= on NM_021190.4) | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs764866338, COSV64626357; called by muse, mutect2, varscan2
- PTGS1 | c.1254T>G p.V418= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- PXK | c.1059G>T p.S353= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as COSV100243833, COSV57093918; called by muse, mutect2, varscan2
- RAPGEF6 | c.2700G>A p.L900= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as rs1352268200; called by muse, mutect2
- RBM23 | c.816C>T p.F272= (on ENST00000359890 / NM_001077351.2; = p.F256= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as COSV100321409; called by muse, mutect2
- RBP3 | c.3003C>A p.A1001= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- RGS1 | c.78G>A p.L26= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs1249178663, COSV66506919; called by muse, mutect2, varscan2
- RP1 | c.1791T>G p.T597= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99607758; called by muse, mutect2, varscan2
- RPS6KC1 | c.1842A>T p.G614= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100873925; called by muse, mutect2
- RTL5 | c.300G>C p.S100= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101030159, COSV65453422; called by muse, mutect2
- RYR2 | c.14229T>A p.L4743= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100770910; called by muse, mutect2, varscan2
- SALL1 | c.540G>A p.G180= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs778212303, COSV99174563; called by muse, varscan2
61 further variants in this file (0 protein-altering or splice-affecting, 36 silent, 25 other) are not listed here.
